Somatic mutation profile of tumor specimen ASCProject_0055_T1_WES (aliquot ASCProject_0055_T1_WES_1) from CMI case ASCProject_0055, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.8 years (13,822 days).
Specimen ASCProject_0055_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c4c459c-6c89-482c-b2ef-a49e2e1a6424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0055_SALIVA (Saliva), aliquot ASCProject_0055_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad8a138f-b511-4795-a4d5-90a274691012

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Intron 4, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 2, Splice Site 2, 5'UTR 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 52/137 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as rs45517340, CD052530, CM991214, COSV51915136; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- BARHL2 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs764468861, COSV100966082; called by muse, mutect2, varscan2
- CDH17 | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV50327264; called by muse, mutect2, varscan2
- DBN1 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as rs759018794; called by muse, mutect2
- DCAF12L1 | c.1169C>G p.T390S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64422984; called by muse, mutect2, varscan2
- GPRC5B | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1423448490; called by muse, mutect2, varscan2
- NCAM2 | c.2035G>C p.V679L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1323270729; called by muse, mutect2, varscan2
- NF1 | c.6704+1G>C p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 48/435 reads (11%) | catalogued as rs1060500376, CD040919, CS041539, CS137212, CS982281, COSV62197389, COSV62217889, COSV62218380; called by muse, mutect2, varscan2
- PSG6 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs529836601; called by muse, mutect2, varscan2
- SULT1C2 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99264927; called by muse, mutect2, varscan2
- TLN1 | c.4663C>T p.R1555C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs796217856, COSV59206441; called by muse, mutect2
- ARHGAP5 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID2 | c.1940del p.G647Efs*16 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | called by mutect2, pindel*
- BMPER | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 102/290 reads (35%) | called by muse, mutect2, varscan2
- CARD17 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.314); called by muse, mutect2
- CARMIL1 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- CCDC18 | c.3133A>G p.I1045V (on ENST00000343253 / NM_001306076.1; = p.I1046V on NM_206886.4) | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CEP85L | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAH5 | c.9849del p.K3283Nfs*9 | Frame Shift Del (DEL) | VAF 93/698 reads (13%) | called by mutect2, pindel, varscan2
- EVC2 | c.2701C>A p.L901M | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- GINS3 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.163); called by muse, mutect2
- GPC6 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- GRIN2A | c.1007+8A>T | Splice Region (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2
- KIF13B | c.3787A>T p.M1263L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- LRRC37B | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC1 | c.1141T>A p.F381I | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.587); called by muse, mutect2
- MAGEE1 | c.1600A>T p.R534W | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MKI67 | c.3338G>T p.G1113V | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NLGN4X | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PHKB | c.2914A>T p.M972L | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.147); called by muse, mutect2
- RGS7 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- RIC8A | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2
- SNED1 | c.4102G>A p.G1368R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM215 | c.578A>C p.E193A | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WASHC2C | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF224 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- ZNF347 | c.2427G>C p.Q809H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AKAP12 | c.4143C>T p.P1381= | Silent (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- CLP1 | c.1131C>T p.N377= | Silent (SNP) | VAF 49/256 reads (19%) | called by muse, mutect2, varscan2
- FAM47C | c.582G>A p.R194= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- IKZF1 | c.1098G>A p.Q366= | Silent (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- MYH4 | c.5586C>A p.R1862= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2, varscan2
- ORC3 | c.1548A>G p.S516= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV57641047; called by muse, mutect2, varscan2
- SVOPL | c.396G>A p.S132= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs538349256; called by muse, mutect2, varscan2
- TCF23 | c.360C>T p.L120= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs370405355; called by muse, mutect2
- TRO | c.21C>T p.Y7= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs759120949, COSV51498354; called by muse, mutect2, varscan2
- TYSND1 | c.201C>G p.A67= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- AC116655.1 | n.19G>T | RNA (SNP) | VAF 57/316 reads (18%) | called by muse, mutect2, varscan2
- ADAM9 | c.*1160A>G | 3'UTR (SNP) | VAF 37/233 reads (16%) | catalogued as rs541304766; called by muse, mutect2, varscan2
- C2CD6 | c.1581+2243A>T | Intron (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- CAMKMT | c.377-72780T>A | Intron (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- PIK3R6 | c.-173C>T | 5'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61003366; called by muse, mutect2, varscan2
- RNASEH2B | c.699-44C>T | Intron (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- SLC3A1 | c.766-342C>A | Intron (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2
- VPS11 | c.-165A>G | 5'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- ZNF827 | c.*436G>A | 3'UTR (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
